Somatic mutation profile of tumor specimen MP2PRT-PASTPH-TMP1-A (aliquot MP2PRT-PASTPH-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PASTPH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,114 days).
Specimen MP2PRT-PASTPH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b88594db-ca98-4ab6-8e12-b44d225c03bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASTPH-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASTPH-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b9cee91-4907-4144-b943-4245c07d41de

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Splice Site 3, In Frame Del 1, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMTA1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 170/542 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57887236, COSV57906544; called by muse, mutect2, varscan2
- CSMD2 | c.9559+1G>A p.X3187_splice | Splice Site (SNP) | VAF 117/293 reads (40%) | catalogued as COSV53910136; called by muse, mutect2, varscan2
- H1-6 | c.49A>G p.M17V | Missense Mutation (SNP) | VAF 235/344 reads (68%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs776075576; called by muse, mutect2, varscan2
- MUC2 | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 150/519 reads (29%) | SIFT deleterious (0); catalogued as rs377233361; called by muse, mutect2, varscan2
- COG3 | c.175-1G>A p.X59_splice | Splice Site (SNP) | VAF 46/142 reads (32%) | called by muse, varscan2
- GARRE1 | c.1573G>A p.G525R | Missense Mutation (SNP) | VAF 18/604 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2
- H1-2 | c.278_292delinsCCA p.L93_G98delinsPS | In Frame Del (DEL) | VAF 190/380 reads (50%) | called by pindel, varscan2*
- IGHV3-35 | c.347_348insA p.R117Efs*? | Frame Shift Ins (INS) | VAF 60/178 reads (34%) | called by mutect2, pindel*, varscan2
- MAD1L1 | c.665A>G p.E222G | Missense Mutation (SNP) | VAF 138/404 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- RGMB | c.190G>A p.V64M (on ENST00000513185 / NM_001366508.1; = p.V105M on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 186/546 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- SLC13A4 | c.99+1G>A p.X33_splice | Splice Site (SNP) | VAF 180/501 reads (36%) | called by muse, mutect2, varscan2
- ZEB2 | c.3215A>G p.Q1072R | Missense Mutation (SNP) | VAF 171/538 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- FOXP3 | c.1233G>T p.L411= | Silent (SNP) | VAF 254/773 reads (33%) | called by muse, mutect2, varscan2
